TARGET case TARGET-10-PAREBH — Acute Lymphoblastic Leukemia - Phase II (TARGET-ALL-P2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ba122130-d2b9-5332-a1a0-b13642c8b4aa

Demographics
Sex at birth: male; Race: american indian or alaska native; Ethnicity: not hispanic or latino; Age at index: 18 years; Vital status: Dead; Days to death: 110 days.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 18.5 years (6,768 days); Year of diagnosis: 2007; Days to last follow up: 110 days.
   Treatment given: Protocol identifier: AALL0232.

Follow-up (1 entry)
- Days to follow up: 110 days; Days to first event: 110 days; First event: Death; Year of follow up: 2007.

Molecular and laboratory tests (laboratory values grouped by visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- BCR–ABL1 fusion: Negative.
- ETV6–RUNX1 fusion (FISH): Negative.
- KMT2A rearrangement (FISH): Negative.
- TCF3–PBX1 translocation: Negative.
- Trisomy 10: Negative.
- Trisomy 4: Negative.
- Day 0: Leukocytes 171 ×10³/µL.
- Day 8: Bone Marrow blast count 81%; Minimal Residual Disease (Flow Cytometry) 12.4%.
- Day 15: Bone Marrow blast count 6%.
- Day 29: Bone Marrow blast count 1%; Minimal Residual Disease (Flow Cytometry) 3%.
- Day 43: Bone Marrow blast count 1%; Minimal Residual Disease (Flow Cytometry) 2.2%.

Other clinical attributes
- Day 0: Comorbidities: Down Syndrome; Risk factors: Down Syndrome.

Biospecimens (2 samples)
- Sample TARGET-10-PAREBH-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Sample TARGET-10-PAREBH-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_Blast_Data_20230727.xlsx, for sample TARGET-10-PAREBH-09A-01D:
- Blast %: >70

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_II_Validation_20230727.xlsx:
- Overall Survival Time in Days: 110
- WBC at Diagnosis: 171.2
- CNS Status at Diagnosis: CNS 2b
- Testicular Involvement: No
- MRD Day 8: 12.4
- MRD Day 8 Sensitivity: 0.01
- MRD Day 29: 3
- MRD Day 29 Sensitivity: 0.01
- MRD Day 43: 2.2
- Bone Marrow Site of Relapse: No
- CNS Site of Relapse: No
- Testes Site of Relapse: No
- Other Site of Relapse: No
- ETV6 RUNX1 Fusion Status: Negative
- TRISOMY 4 10 Status: Negative
- MLL Status: Negative
- TCF3 PBX1 Status: Negative
- BCR ABL1 Status: Negative
- BMA Blasts Day 8: 81
- BMA Blasts Day 15: 6
- BMA Blasts Day 29: 1
- BMA Blasts Day 43: 1
- Karyotype: 47,XY,+21c[20]
- Down Syndrome: Yes
- DNA Index: 1
- Alternate Therapy: Chemotherapy
- Cell of Origin: B Cell ALL
